Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOM, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAOM-01A (Primary Tumor).

[page 1 of 2]
Name:

Operative Procedure: orchiectomy
- Specimen Source: RIGHT TESTIS
- Gross Exam Date:
- Physician:

ICD 0.3
Seminoma NOS 9061/3
Site @ Testis NOS C629
9/3/31/14

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA OF TESTIS (7 CM), UNIFOCAL, right orchiectomy. (see note)
2. SPERMATIC CORD MARGIN AND OTHER MARGINS ARE NOT INVOLVED BY TUMOR.
3. TUMOR INVASION TO EPIDIDYMIS.
4. NO LYMPHOVASCULAR INVASION IDENTIFIED.
5. INTRATUBULAR GERM CELL NEOPLASIA
6. SEMINIFEROUS TUBULES WITH ADVANCED ATROPHY AND WITHOUT EVIDENCE OF SPERMATOGENESIS
7. pT1NXMX

Note: The tumor cells are strongly positive for c-kit and focally positive for beta-HCG. They are negative for AE1/AE3 keratin stains. The immunocytochemical findings are consistent with the diagnosis, although the significance of the beta-HCG seminoma cells is uncertain.

GROSS DESCRIPTION:

The specimen is received in one part, labeled with patient's name and hospital number and labeled "right testis" and consists of 150 gram orchiectomy specimen including 7.5 x 6 x 4 cm testis, 5 x 2 x 1.5 cm epididymis and 7.5 cm in length and 1 cm in diameter spermatic cord. The outer surface is inked in black. At the base of epididymis and 0.3 cm from the tunica albuginea there is a 7 x 6 x 4 cm white-tan fleshy well circumscribed mass with focal areas of hemorrhage and the mass almost replaces all normal testicular parenchyma. The spermatic cord consists of vas deferens, arteries and veins and is unremarkable. R-12.

Summary of Cassettes:

- 1-5. Mass.
6. Mass and the base of the epididymis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT
---	-----------------------------	---------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
TISSUE REPORT

Name:

Operative Procedure: orchiectomy

- Specimen Source: RIGHT TESTIS
- Gross Exam Date:
- Physician:

Pager No.:

7. Mass and tunica vaginalis.
8. Tumor and adjacent testis.
9. Spermatic cord resection margin.
10. Spermatic cord midportion.
11. Spermatic cord peritesticular portion.
12. Epididymis from the posterior surface of the testis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 2

Source: NCI Genomic Data Commons file 0c0525f7-0431-459c-bb9f-ee03470cdbee (TCGA-XE-AAOM-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).